Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A28R, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A28R-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Thyroid nodule.

PROCEDURE: Unanswered.

SPECIFIC CLINICAL QUESTION: Unanswered.

OUTSIDE TISSUE DIAGNOSIS: Unanswered.

PRIOR MALIGNANCY: Unanswered.

CHEMORADIATION THERAPY: Unanswered.

ORGAN TRANSPLANT: Unanswered.

IMMUNOSUPPRESSION: Unanswered.

OTHER DISEASES: Unanswered.

1CD-0-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

lw 5/25/11

FINAL DIAGNOSIS:**PART 1: THYROID, TOTAL THYROIDECTOMY (21 grams)-**

- A. PAPILLARY THYROID CARCINOMA (1.5 CM), CONVENTIONAL TYPE, RIGHT LOBE (see comment).
- B. THE CARCINOMA IS CONFINED TO THE THYROID.
- C. ANGIOLYMPHATIC INVASION INCLUDING PSAMMOMA BODIES IN THE INTERSTITIUM.
- D. THREE LYMPH NODES, NO TUMOR PRESENT (0/3).
- E. PATHOLOGIC STAGE: pT1b N0.
- F. CHRONIC LYMPHOCYTIC THYROIDITIS.
- G. NODULAR THYROID.
- H. RIGHT INFERIOR PARATHYROID TISSUE.

Collection Date: _____

PART 2: LYMPH NODES, BILATERAL CENTRAL COMPARTMENT, EXCISION -

- A. SEVENTEEN LYMPH NODES, NO TUMOR PRESENT (0/17).
- B. THYROID TISSUE WITH CHRONIC LYMPHOCYTIC THYROIDITIS.

COMMENT:

Immunohistochemical stains for HBME-1 and Galactin-3 are negative excluding the possibility for an additional focus.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY THYROID TUMORS**

SPECIMEN TYPE: Total Thyroidectomy
TUMOR SITE: Right Lobe
TUMOR FOCALITY: Unifocal
TUMOR SIZE (largest nodule): Greatest Dimension: 1.5 cm
HISTOLOGIC TYPE**: Papillary carcinoma
PRIMARY TUMOR (pT): pT1b
REGIONAL LYMPH NODES (pN): pN0

Number of regional lymph nodes examined: 20
Number of regional lymph nodes involved: 0

EXTRANODAL EXTENSION: Not identified
DISTANT METASTASIS (pM): Not applicable
EXTRATHYROIDAL EXTENSION: Not identified
MARGINS: Margins uninvolved by carcinoma
LYMPH-VASCULAR INVASION: Present
ADDITIONAL PATHOLOGIC FINDINGS: Other: chronic lymphocytic thyroiditis and nodular thyroid.

Diagnostic Discrepancy		

lw 5/25/11

Source: NCI Genomic Data Commons file 78725e3f-6bdc-47b0-8acb-29b1ff854c49 (TCGA-BJ-A28R.163FA0B6-9488-47D1-AAB6-F4FD5F8ACFFD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).